Somatic mutation profile of tumor specimen MP2PRT-PANZZI-TMP1-A (aliquot MP2PRT-PANZZI-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANZZI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,123 days).
Specimen MP2PRT-PANZZI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e0067c3-0e2f-47b7-909f-07cb80279414.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANZZI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANZZI-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ecf7eb5-7667-4153-bc69-211f45be823b

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 6, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.4189G>A p.V1397M | Missense Mutation (SNP) | VAF 119/303 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186328765, COSV61991376; called by muse, mutect2, varscan2
- CACNA1I | c.6502G>A p.A2168T | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV60802839; called by muse, mutect2
- MAN1A2 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1328562004, COSV62979400; called by muse, mutect2, varscan2
- MN1 | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 53/543 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); catalogued as COSV100180086; called by muse, mutect2
- MYO3A | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56320538; called by muse, mutect2, varscan2
- PBX1 | c.393_401dup p.A133_A135dup | In Frame Ins (INS) | VAF 74/343 reads (22%) | catalogued as rs770921151; called by mutect2, varscan2
- MELTF | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ACSS3 | c.369T>C p.N123= | Silent (SNP) | VAF 54/197 reads (27%) | called by muse, mutect2, varscan2
- BSDC1 | c.1224G>A p.V408= | Silent (SNP) | VAF 103/296 reads (35%) | catalogued as rs1430341501; called by muse, mutect2, varscan2
- CACNA1H | c.2304C>T p.A768= | Silent (SNP) | VAF 57/457 reads (12%) | called by muse, mutect2, varscan2
- FIBIN | c.330C>T p.D110= | Silent (SNP) | VAF 64/369 reads (17%) | catalogued as rs1306539162, COSV59412428; called by muse, mutect2, varscan2
- L1CAM | c.630C>T p.H210= | Silent (SNP) | VAF 273/307 reads (89%) | catalogued as rs28933683, CM941029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB15 | c.1035G>A p.P345= | Silent (SNP) | VAF 72/255 reads (28%) | catalogued as rs1554291969, COSV51427231; called by muse, mutect2, varscan2
- TNXB | c.11178C>T p.F3726= (on ENST00000647633; = p.F3479= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/438 reads (26%) | catalogued as rs779290669, COSV64483375; called by muse, mutect2, varscan2
- TOGARAM2 | c.102G>A p.P34= | Silent (SNP) | VAF 123/261 reads (47%) | catalogued as rs201622059; called by muse, mutect2, varscan2
- USP48 | c.333G>A p.L111= | Silent (SNP) | VAF 91/308 reads (30%) | called by muse, mutect2, varscan2
